Somatic mutation profile of tumor specimen C3N-03005-03 (aliquot CPT0247940006) from CPTAC case C3N-03005, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G2; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen C3N-03005-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f731b004-ed0e-41c7-bee9-3f4da235e952.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03005-31 (Blood Derived Normal), aliquot CPT0247960002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fec932a3-dada-4736-a3e2-9cd77bf76434

The open-access MAF lists 92 somatic variants for this specimen: 60 protein-altering or splice-affecting, 25 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, Silent 25, Nonsense Mutation 4, Frame Shift Del 3, Intron 2, Splice Site 2, 5'UTR 2, 3'UTR 1, Splice Region 1, 3'Flank 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTCF | c.615_618del p.K206Pfs*15 | Frame Shift Del (DEL) | VAF 69/604 reads (11%) | catalogued as rs1555534147; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- CTCF | c.1061C>T p.S354F | Missense Mutation (SNP) | VAF 27/198 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV50461395, COSV50462411; called by muse, mutect2, varscan2
- PTEN | c.388C>G p.R130G | Missense Mutation (SNP) | VAF 79/530 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AFMID | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 54/329 reads (16%) | SIFT tolerated (0.77); PolyPhen benign (0.005); catalogued as rs200095741; called by muse, mutect2, varscan2
- AP3B1 | c.1021C>T p.R341C | Missense Mutation (SNP) | VAF 29/281 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs964935640, COSV99079483; called by muse, mutect2, varscan2
- BRINP1 | c.1561C>T p.R521C | Missense Mutation (SNP) | VAF 45/207 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs987725274, COSV56293277; called by muse, mutect2, varscan2
- CACTIN | c.316G>A p.A106T | Missense Mutation (SNP) | VAF 44/427 reads (10%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0); catalogued as rs374661733; called by muse, mutect2, varscan2
- CCDC58 | c.397C>T p.R133C | Missense Mutation (SNP) | VAF 13/228 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.156); catalogued as rs1381976878; called by muse, mutect2
- CCNA1 | c.730C>G p.R244G | Missense Mutation (SNP) | VAF 57/342 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55223707; called by muse, mutect2, varscan2
- CHD6 | c.3700C>T p.R1234W | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778466031, COSV58558991; called by muse, mutect2, varscan2
- CLSTN2 | c.601G>A p.V201I | Missense Mutation (SNP) | VAF 61/331 reads (18%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.57); catalogued as rs762779163, COSV71724227, COSV71724666; called by muse, mutect2, varscan2
- COL3A1 | c.3607G>A p.A1203T | Missense Mutation (SNP) | VAF 34/192 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0.038); catalogued as rs550665335, CM1512473, COSV58595485, COSV58597783; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CSMD1 | c.2996G>A p.R999K (on ENST00000520002; = p.R998K on NM_033225.6) | Missense Mutation (SNP) | VAF 28/690 reads (4%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.982); catalogued as rs1440352435; called by muse, mutect2
- CTNND2 | c.2269G>T p.D757Y | Missense Mutation (SNP) | VAF 34/334 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58896895; called by muse, mutect2
- F8 | c.2441G>A p.R814Q | Missense Mutation (SNP) | VAF 22/243 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs782158350, COSV64273781; called by muse, mutect2
- FCRL4 | c.1133G>A p.R378K | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT tolerated (0.35); PolyPhen benign (0.083); catalogued as COSV99619923; called by muse, varscan2
- GAS2L3 | c.649-1G>A p.X217_splice | Splice Site (SNP) | VAF 8/80 reads (10%) | catalogued as rs1356182225; called by muse, mutect2
- HIP1R | c.319C>T p.R107W | Missense Mutation (SNP) | VAF 49/362 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs530896606; called by muse, mutect2, varscan2
- HYDIN | c.6980G>A p.R2327H | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as rs781652242, COSV59249041; called by mutect2, varscan2
- KIAA0825 | c.626T>A p.I209K | Missense Mutation (SNP) | VAF 30/143 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.165); catalogued as rs896604968; called by muse, mutect2, varscan2
- KLHL26 | c.1288G>A p.V430M | Missense Mutation (SNP) | VAF 23/121 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs751466088; called by muse, mutect2, varscan2
- KMT2D | c.8366G>A p.R2789Q | Missense Mutation (SNP) | VAF 34/199 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.629); catalogued as rs1208681909, COSV56417455; called by muse, mutect2, varscan2
- NAA11 | c.247C>T p.R83C | Missense Mutation (SNP) | VAF 62/319 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.848); catalogued as rs1374492628, COSV54516499; called by muse, mutect2, varscan2
- PCDH9 | c.2086G>A p.V696M | Missense Mutation (SNP) | VAF 21/142 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs766490363; called by muse, mutect2, varscan2
- PCDHB6 | c.1516G>A p.A506T | Missense Mutation (SNP) | VAF 125/978 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as rs782451628; called by muse, mutect2, varscan2
- POU4F2 | c.1046G>A p.R349H | Missense Mutation (SNP) | VAF 28/197 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs751460020, COSV55586096; called by muse, mutect2, varscan2
- PRKCG | c.1912C>T p.R638C | Missense Mutation (SNP) | VAF 48/382 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as rs1407058714, COSV54726211; called by muse, mutect2, varscan2
- PTEN | c.1026G>A p.K342= | Splice Region (SNP) | VAF 18/156 reads (12%) | catalogued as rs398123314, CM132269, COSV100911310, COSV64292596, COSV64307072; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RSF1 | c.2908C>T p.R970C | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV57836149; called by muse, mutect2, varscan2
- RTL1 | c.1471G>A p.E491K | Missense Mutation (SNP) | VAF 22/164 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.091); catalogued as rs539160660, COSV101128161, COSV99062614; called by muse, mutect2, varscan2
- SERPINA6 | c.803C>T p.P268L | Missense Mutation (SNP) | VAF 82/500 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201880274, CM150499; called by muse, mutect2, varscan2
- SLC26A1 | c.2062C>T p.R688* | Nonsense Mutation (SNP) | VAF 24/168 reads (14%) | catalogued as rs774975166; called by muse, mutect2, varscan2
- THSD7B | c.2459C>T p.T820M | Missense Mutation (SNP) | VAF 44/273 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs568467115, COSV55677825; called by muse, mutect2, varscan2
- TSC2 | c.577G>C p.E193Q | Missense Mutation (SNP) | VAF 95/553 reads (17%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.573); catalogued as CM090954; called by muse, mutect2, varscan2
- UBXN11 | c.1145G>A p.R382Q (on ENST00000374221 / NM_183008.2; = p.R349Q on NM_145345.2) | Missense Mutation (SNP) | VAF 17/296 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as rs756092849; called by muse, mutect2
- ZFHX4 | c.958G>A p.A320T | Missense Mutation (SNP) | VAF 55/241 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50927048, COSV51477020; called by muse, mutect2, varscan2
- ZNF717 | c.2081G>A p.R694K | Missense Mutation (SNP) | VAF 37/282 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs1194832780; called by muse, mutect2, varscan2
- AASS | c.1711G>T p.V571F | Missense Mutation (SNP) | VAF 72/567 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ALDOA | c.928G>A p.A310T (on ENST00000642816 / NM_001243177.4; = p.A256T on NM_184041.5) | Missense Mutation (SNP) | VAF 142/782 reads (18%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.782); called by muse, mutect2, varscan2
- ANP32B | c.5A>G p.D2G | Missense Mutation (SNP) | VAF 35/233 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.385); called by muse, mutect2, varscan2
- CCDC86 | c.499C>T p.Q167* | Nonsense Mutation (SNP) | VAF 42/259 reads (16%) | called by muse, mutect2, varscan2
- DENND10 | c.791C>T p.P264L | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- FCN2 | c.581A>T p.D194V | Missense Mutation (SNP) | VAF 30/267 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- IGF1R | c.341A>G p.N114S | Missense Mutation (SNP) | VAF 99/615 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- MBD1 | c.1150C>T p.R384W (on ENST00000269468 / NM_001323950.1; = p.R328W on NM_002384.2) | Missense Mutation (SNP) | VAF 63/403 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- MOG | c.710-1G>A p.X237_splice | Splice Site (SNP) | VAF 71/521 reads (14%) | called by muse, mutect2, varscan2
- ODR4 | c.1314T>A p.F438L | Missense Mutation (SNP) | VAF 41/337 reads (12%) | SIFT tolerated (0.97); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR10G8 | c.390G>T p.R130S | Missense Mutation (SNP) | VAF 46/353 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- PIK3R1 | c.1004G>A p.W335* (on ENST00000521381 / NM_181523.3; = p.W65* on NM_181504.4) | Nonsense Mutation (SNP) | VAF 16/158 reads (10%) | called by muse, mutect2
- PLXNC1 | c.2982C>G p.D994E | Missense Mutation (SNP) | VAF 32/300 reads (11%) | SIFT tolerated (0.92); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- PTK2 | c.1865C>T p.P622L | Missense Mutation (SNP) | VAF 57/383 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- RUSC2 | c.4409A>G p.K1470R | Missense Mutation (SNP) | VAF 50/311 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- SH3PXD2A | c.272T>C p.V91A | Missense Mutation (SNP) | VAF 62/336 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- TAOK1 | c.1964A>G p.Q655R | Missense Mutation (SNP) | VAF 54/285 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- TCEANC | c.339G>T p.E113D (on ENST00000380600 / NM_001297563.2; = p.E143D on NM_152634.4) | Missense Mutation (SNP) | VAF 49/178 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- TCERG1 | c.1156G>A p.V386I | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- TCIRG1 | c.2044_2056del p.P682* | Frame Shift Del (DEL) | VAF 40/475 reads (8%) | called by mutect2, pindel
- TSC1 | c.2461del p.V821Cfs*28 | Frame Shift Del (DEL) | VAF 65/370 reads (18%) | called by mutect2, pindel, varscan2
- XBP1 | c.436G>T p.E146* | Nonsense Mutation (SNP) | VAF 22/140 reads (16%) | called by muse, varscan2
- ZNF287 | c.2198C>T p.A733V | Missense Mutation (SNP) | VAF 26/165 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ADCY8 | c.474C>T p.R158= | Silent (SNP) | VAF 55/409 reads (13%) | called by muse, mutect2, varscan2
- ARID3A | c.675C>T p.Y225= | Silent (SNP) | VAF 102/672 reads (15%) | catalogued as rs750779148; called by muse, mutect2, varscan2
- B4GALNT4 | c.2844C>T p.C948= | Silent (SNP) | VAF 38/234 reads (16%) | catalogued as rs745889640, COSV57322223; called by muse, mutect2, varscan2
- CLCNKB | c.774C>T p.S258= | Silent (SNP) | VAF 35/195 reads (18%) | catalogued as rs1200797674, COSV100990443; called by muse, mutect2, varscan2
- DHX58 | c.816T>C p.A272= | Silent (SNP) | VAF 9/63 reads (14%) | called by muse, mutect2
- DNAH1 | c.7815C>T p.Y2605= | Silent (SNP) | VAF 44/460 reads (10%) | catalogued as rs764179591, COSV101327031; called by muse, mutect2
- FLI1 | c.126C>T p.Y42= | Silent (SNP) | VAF 54/352 reads (15%) | catalogued as rs779389569, COSV61378536; called by muse, mutect2, varscan2
- GRM6 | c.222C>T p.Y74= | Silent (SNP) | VAF 43/337 reads (13%) | catalogued as rs778393434, COSV51435478; called by muse, mutect2, varscan2
- GTSE1 | c.1965C>A p.V655= | Silent (SNP) | VAF 109/608 reads (18%) | catalogued as COSV71889458; called by muse, mutect2, varscan2
- KIF7 | c.2538G>T p.T846= | Silent (SNP) | VAF 61/323 reads (19%) | called by muse, mutect2, varscan2
- MAP4K2 | c.1126C>T p.L376= | Silent (SNP) | VAF 25/150 reads (17%) | called by muse, mutect2, varscan2
- METTL21C | c.567C>T p.Y189= | Silent (SNP) | VAF 37/243 reads (15%) | catalogued as rs749395419; called by muse, mutect2, varscan2
- MYH8 | c.3858A>G p.E1286= | Silent (SNP) | VAF 110/597 reads (18%) | called by muse, mutect2, varscan2
- PARD3B | c.1476C>T p.S492= | Silent (SNP) | VAF 44/205 reads (21%) | catalogued as rs549890679; called by muse, mutect2, varscan2
- PCDHB8 | c.87G>A p.A29= | Silent (SNP) | VAF 50/2058 reads (2%) | called by muse, mutect2
- PPFIA4 | c.3435G>A p.P1145= (on ENST00000447715; = p.P1146= on NM_001304331.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/62 reads (19%) | called by muse, mutect2, varscan2
- PRAMEF12 | c.543G>A p.K181= | Silent (SNP) | VAF 67/565 reads (12%) | catalogued as rs921598101; called by muse, mutect2, varscan2
- RCHY1 | c.33C>T p.S11= | Silent (SNP) | VAF 20/137 reads (15%) | catalogued as COSV61007834; called by muse, mutect2, varscan2
- RTL1 | c.1110G>T p.L370= | Silent (SNP) | VAF 25/245 reads (10%) | catalogued as rs1395788877; called by muse, mutect2
- STX11 | c.783G>A p.A261= | Silent (SNP) | VAF 56/317 reads (18%) | catalogued as rs1317316024; called by muse, mutect2, varscan2
- TMEM65 | c.366G>A p.A122= | Silent (SNP) | VAF 39/188 reads (21%) | catalogued as rs532224599, COSV52632339; called by muse, mutect2, varscan2
- TRAPPC12 | c.1614G>A p.R538= | Silent (SNP) | VAF 23/228 reads (10%) | called by muse, mutect2
- UBE3C | c.417A>G p.T139= | Silent (SNP) | VAF 9/110 reads (8%) | catalogued as rs776509878; called by muse, mutect2
- ZNF461 | c.327G>A p.Q109= | Silent (SNP) | VAF 18/137 reads (13%) | catalogued as COSV64453298; called by mutect2, varscan2
- ZNF692 | c.42G>A p.R14= | Silent (SNP) | VAF 12/104 reads (12%) | called by muse, mutect2, varscan2
- ADORA2A | c.-33C>T | 5'UTR (SNP) | VAF 17/126 reads (13%) | catalogued as rs200301292; called by muse, mutect2, varscan2
- FAM207A | chr21:44939567 G>A | 5'Flank (SNP) | VAF 74/526 reads (14%) | called by muse, mutect2, varscan2
- FILIP1L | c.*81G>A | 3'UTR (SNP) | VAF 18/124 reads (15%) | catalogued as rs1457516382, COSV100640465; called by muse, mutect2, varscan2
- GABRA1 | c.256-43A>G | Intron (SNP) | VAF 27/218 reads (12%) | called by muse, mutect2, varscan2
- MRPL27 | c.241-592C>T | Intron (SNP) | VAF 16/155 reads (10%) | called by muse, mutect2, varscan2
- RNU6-1178P | chr17:20893440 A>G | 3'Flank (SNP) | VAF 24/170 reads (14%) | called by muse, mutect2, varscan2
- RPS6KA4 | c.-41C>A | 5'UTR (SNP) | VAF 4/34 reads (12%) | called by muse, varscan2
